Somatic mutation profile of tumor specimen MP2PRT-PAUKYU-TMP1-A (aliquot MP2PRT-PAUKYU-TMP1-A-1-0-D-A818-36) from MP2PRT case MP2PRT-PAUKYU, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 2.3 years (826 days).
Specimen MP2PRT-PAUKYU-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ba5adfae-9e79-426f-b3e2-d9a32c4a18b1.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAUKYU-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAUKYU-NB1-A-1-0-D-A818-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/74107e27-7ce3-4410-96ef-17b8ba7c4d0d

The open-access MAF lists 6 somatic variants for this specimen: 4 protein-altering or splice-affecting, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Nonsense Mutation 2, 5'Flank 2, Frame Shift Ins 1, Missense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IRF1 | c.385C>T p.R129* | Nonsense Mutation (SNP) | VAF 38/275 reads (14%) | catalogued as COSV55376240; called by muse, mutect2, varscan2
- SALL2 | c.1801C>T p.R601W | Missense Mutation (SNP) | VAF 79/382 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as rs768526871, COSV58103015; called by muse, mutect2, varscan2
- C1orf94 | c.301G>T p.E101* | Nonsense Mutation (SNP) | VAF 13/228 reads (6%) | called by muse, mutect2
- SLC4A7 | c.2029dup p.I677Nfs*4 | Frame Shift Ins (INS) | VAF 73/196 reads (37%) | called by mutect2, pindel, varscan2
- C2orf16 | chr2:27576113 G>T | 5'Flank (SNP) | VAF 12/358 reads (3%) | called by muse, mutect2
- IGHV1-58 | chr14:106627248 ins A | 5'Flank (INS) | VAF 88/257 reads (34%) | called by mutect2, pindel, varscan2
